Surgical pathology report (de-identified scan), TCGA case TCGA-CQ-5323, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Health Network, Toronto, specimen TCGA-CQ-5323-01A (Primary Tumor).

[page 1 of 4]
Specimen(s) Received

1. Oral-Cavity: Right marginal mandibulectomy - suture posterior
2. Oral Cavity: Right anterior margin
3. Oral Cavity: Right medial margin QS
4. Oral Cavity: Right anterior margin QS
5. Oral Cavity: Right posterior margin QS
6. Oral Cavity: Right lateral margin QS
7. Oral Cavity: Right deep muscle margin QS
8. Neck: Right level 1A
9. Neck: Right level 1B
10. Neck: Right level 2A
11. Neck: Right level 3 & 4
12. Surgical Waste

Diagnosis

1. Right marginal mandibulectomy:
- In-situ and invasive squamous cell carcinoma, moderately differentiated.
- a. Maximum tumour dimension 1.8 cm.
- b. No perineural invasion present.
- c. No lymphovascular invasion present.
- d. Anterior margin positive for squamous carcinoma in-situ (CIS).
- e. All other margins are negative for in-situ and invasive carcinoma.
- f. Bone sections pending decalcification and will be reported in an addendum.
2. Right anterior margin:
- In-situ and focally invasive squamous cell carcinoma.
- a. Squamous carcinoma in-situ (CIS) is present at the mucosal margin.
- b. Bone sections pending decalcification and will be reported in an addendum.
3. Right medial margin:
- Squamous mucosa, negative for tumour.
4. Right anterior margin:
- Positive for squamous carcinoma in-situ (CIS). No invasive carcinoma present.
5. Right posterior margin:
- Squamous mucosa, negative for tumour.
6. Right lateral margin:

[page 2 of 4]
Surgical Pathology Consultation Report

- Squamous mucosa, negative for tumour.
- 7. Right deep muscle margin:
- Skeletal muscle, negative for tumour.
- 8. Right neck; level IA:
- Twelve lymph nodes, negative for tumour (0/12).
- 9. Right neck; level IB:
- Three lymph nodes, negative for tumour (0/3).
- Submandibular gland with no pathologic changes.
- 10. Right neck; level IIA:
- Two lymph nodes, negative for tumour (0/2).
- 11. Right neck; levels III & IV:
- One lymph node, negative for tumour (0/1).
- 12. Surgical Waste:
- Skin with no pathologic changes (gross examination only).

Clinical History

oral ca

Gross Description

1. The specimen container labeled with the patient's name and as "right marginal mandibulectomy", contains one piece of right floor of mouth mucosal tissue measuring 4.0 cm SI x 3.0 cm ML x 5.5 cm AP. It includes a portion of upper posterior mandible body with 1 tooth. There is a tumor arising on the mucosal surface. The tumor measures 1.5 cm SI x 1.5 cm ML x 1.8 cm AP. The tumor is elevated. There is no involvement of bone by the tumor. The tumor is located at 0.7 cm from the closest anterior margin. Remaining margins are as follows: Medial 1.0, posterior 1.8, lateral 1.8 cm respectively. The resection margins are painted with silver nitrate. On sectioning, a small portion of gland measuring 0.8 x 0.4 x 0.4 cm are included in the submucosa anterior-medial part of the specimen. Three pieces of tumor and three pieces of mucosa are taken by tissue bank. Representative sections are submitted as follows:

- 1A-1D mucosa with anterior margin, from lateral to medial
- 1E-1I mucosa with medial margin, from anterior to posterior
- 1J-1M mucosa with posterior margin, from medial to lateral
- 1N-1P mucosa with lateral margin, from posterior to anterior
- 1Q center of tumor with no margin
- 1R mandible bone, anterior margin, en face
- 1S, 1T mandible bone, closest to mucosal tumor
- 1U mandible bone, posterior margin, en face

2. The specimen container labeled with the patient's name and as "right anterior margin", contains one piece of mucosa tissue measuring 2.7 cm SI x 2.5 cm ML x 1.0 cm AP. It includes a portion of mandible bone with one tooth. The posterior resection margin of the this piece of mandibular bone matches the anterior resection margin of the mandibular bone of specimen 1. No tumor is identified in this specimen.

Representative sections are submitted as follows:

- 2A-2C mucosa submitted in total, all sagittal sections, from lateral to medial, with anterior margin painted with India ink
- 2D anterior margin of bone, en face

[page 3 of 4]
Surgical Pathology Consultation Report

3. The specimen container labeled with the patient's name and as "right medial margin", contains one piece of mucosa tissue measuring 2.0 x 0.3 x 0.2 cm received in fresh. This is examined at intraoperative consultation by frozen section performed on the entire specimen.

3A frozen section resubmitted.

4. The specimen container labeled with the patient's name and as "right anterior margin", contains one piece of mucosa tissue measuring 0.6 x 0.2 x 0.1 cm received in fresh. This is examined at intraoperative consultation by frozen section performed on the entire specimen.

4A frozen section resubmitted.

5. The specimen container labeled with the patient's name and as "right posterior margin", contains one piece of mucosa tissue measuring 1.7 x 0.2 x 0.2 cm received in fresh. This is examined at intraoperative consultation by frozen section performed on the entire specimen.

5A frozen section resubmitted.

6. The specimen container labeled with the patient's name and as "right lateral margin", contains one piece of mucosa tissue measuring 1.8 x 0.2 x 0.2 cm received in fresh. This is examined at intraoperative consultation by frozen section performed on the entire specimen.

6A frozen section resubmitted.

7. The specimen container labeled with the patient's name and as "right deep muscle margin", contains one piece of muscle tissue measuring 1.5 x 1.0 x 1.0 cm received in fresh. This is examined at intraoperative consultation by frozen section performed on the entire specimen.

7A frozen section resubmitted.

8. The specimen is labeled with the patient's name and "right neck level 1A". It consists of portion of fibroadipose tissue measuring 3.5 x 3.0 x 1.2 cm. Multiple lymph nodes ranging from 0.3 to 1.4 cm are identified. Representative sections are submitted as follows:

8A the largest lymph node bisected.

8B, 8C multiple lymph nodes

9. The specimen is labeled with the patient's name and "right neck level 1B and". It consists of portion of fibroadipose tissue measuring 4.5 x 3.5 x 1.8 cm. One submandibular gland measuring 4 x 3 x 1.8 cm is identified. Multiple lymph nodes ranging from 1.0 to 1.6 cm are identified. Representative sections are submitted as follows:

9A the largest lymph node bisected

9B two lymph nodes

9C one representative section of submandibular gland

10. The specimen is labeled with the patient's name and "right neck level 2A". It consists of portion of fibroadipose tissue measuring 3.0 x 3.0 x 1.2 cm. Two lymph nodes ranging from 0.7 to 0.8 cm are identified. Representative sections are submitted as follows:

10A two lymph nodes

11. The specimen is labeled with the patient's name and "right neck level 3 & 4". It consists of portion of fibroadipose tissue measuring 4 x 4 x 1.2 cm. One piece of muscle measuring 3 x 3 x 1 cm is identified. One lymph node measuring 0.8 cm and one possible lymph node measuring 0.2 cm are identified. Representative sections are submitted as follows:

11A the lymph node bisected

11B the possible lymph node

12. The specimen container labeled with the patient's name and as "surgical waste", contains one triangle shaped piece of skin tissue measuring 3 x 3 x 1.8 cm. received in 10% buffered formalin. No abnormalities are noted grossly. No tissue is submitted.

[page 4 of 4]
[REDACTED]
Quick Section Diagnosis

- 3. Negative for carcinoma
- 4. High grade dysplasia; focally suspicious but not diagnostic of carcinoma
- 5. Negative for carcinoma
- 6. Negative for carcinoma
- 7. Negative for carcinoma

Addendum

Addendum Diagnosis

- 1. Right marginal mandibulectomy.
Bone negative for carcinoma.
- 2. Right anterior margin.
Bone negative for carcinoma.
-

Source: NCI Genomic Data Commons file b1519d7c-8aec-4ac7-93c3-b2308dc69574 (TCGA-CQ-5323.E0F44701-611C-44CF-A83D-19EC6C1C7364.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).